Surgical pathology report (de-identified scan), TCGA case TCGA-BB-4227, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-4227-01A (Primary Tumor).

[page 1 of 2]
RG PATH REPORT
LECTION DATE/TIME

1st Specimen collected on
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1) LEFT LEVEL 3 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

2) PHARYNX MARGIN, LEFT SUPERIOR (EXCISION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.

3) PHARYNX MARGIN, LEFT INFERIOR (EXCISION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.

4) PHARYNX MARGIN, RIGHT SUPERIOR (EXCISION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.

5) PHARYNX MARGIN, RIGHT INFERIOR (EXCISION): SQUAMOUS MUCOSA, NEGATIVE FOR TUMOR.

6) RIGHT LEVEL 1 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE, SALIVARY GLAND, AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

7) RIGHT NECK LEVEL 2B (DISSECTION): FIVE (5) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

8) RIGHT NECK LEVELS 3 AND 4 (DISSECTION): FOURTEEN (14) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

9) LARYNX, PHARYNX, RIGHT HEMITHYROID, AND RIGHT NECK LEVELS 2 AND 3A (LARYNGOPHARYNGECTOMY, RIGHT HEMITHYROIDECTOMY, AND RIGHT NECK DISSECTION):

SPECIMEN:
Laryngopharyngectomy, right hemithyroidectomy, and right neck levels 2 and 3 dissection

TUMOR SITE:
Hypopharynx (pyriform sinus)

HISTOLOGIC TYPE:
Squamous cell carcinoma with focal sarcomatoid features and necrosis

TUMOR SIZE:
8.5 cm (grossly)

HISTOLOGIC GRADE:
Moderate to poorly differentiated

LYMPH NODES:
Metastatic carcinoma in two (2) of twenty-five (25) ipsilateral lymph nodes. The positive nodes are in level 2. The largest metastatic tumor focus is 4 cm (grossly) (see also parts 1 and 6-8)

EXTRANODAL EXTENSION:
Present

EXTENT OF INVASION:
PRIMARY TUMOR:
pT4a: Tumor invades thyroid gland

REGIONAL LYMPH NODES:
pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension (see also parts 1 and 6-8)

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

TCGA-BB-4227

[page 2 of 2]
[REDACTED]

MARGINS:

Invasive carcinoma involves the inked right superior margin. Invasive carcinoma is less than 1 mm from the inked right anterior, inked right lateral, and inked right posterior margins (see parts 2-5 for additional margins)

VENOUS/LYMPHATIC INVASION:

Indeterminate

PERINEURAL INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

1. Metastatic carcinoma in two (2) of five (5) lymph nodes [Two (2) of four (4) positive lymph nodes in level 2 and zero (0) of one (1) in level 3A)]. The largest metastatic tumor focus is 4 cm (grossly). Extranodal extension is seen.
2. One (1) lymph node, negative for tumor (anterior soft tissue).
3. Focal carcinoma in situ.
4. Lymphocytic thyroiditis.

Parts 4 and 9 of this case were shown in part at the Daily Quality Assurance Conference.

***** End of Diagnosis *****

Clinical History:

SQUAMOUS CELL CARCINOMA

See [REDACTED] for official report.

Reported by:

[REDACTED]

Final Report Signed on [REDACTED]

Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE REPORT, THIS REPORT WAS PREPARED AT:

[REDACTED]

Source: NCI Genomic Data Commons file f8e5166a-9b81-49e2-9581-fed04131c93c (TCGA-BB-4227.97EFCEA3-FA0B-4FE6-9224-094354EB6351.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).